Somatic mutation profile of tumor specimen TCGA-D6-6515-01A (aliquot TCGA-D6-6515-01A-21D-1870-08) from TCGA case TCGA-D6-6515, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 82.4 years (30,099 days).
Specimen TCGA-D6-6515-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edb1c5a5-6168-4e3a-a7c4-fd800922ad18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-6515-10A (Blood Derived Normal), aliquot TCGA-D6-6515-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a8aa906-df9f-491b-a779-f15545d33aa9

The open-access MAF lists 39 somatic variants for this specimen: 26 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/80 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANP32E | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.156); catalogued as COSV100029699; called by muse, mutect2, varscan2
- CACNG7 | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV55817075; called by muse, mutect2, varscan2
- CD163 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs752858863, COSV63129802; called by muse, mutect2, varscan2
- CTDSP2 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101143018; called by muse, mutect2
- DIAPH1 | c.2732A>G p.K911R | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99526709; called by muse, mutect2
- DUSP21 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs766627568, COSV59133782; called by muse, mutect2, varscan2
- HS3ST4 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.895); catalogued as rs1193961102, COSV100501737, COSV104403178; called by muse, mutect2, varscan2
- JAK1 | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100691275; called by muse, mutect2, varscan2
- LYPD3 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99747078; called by muse, mutect2, varscan2
- METTL14 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV101183372, COSV101183403; called by muse, mutect2, varscan2
- MSH4 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as rs867886425, COSV54200076, COSV54204523; called by muse, mutect2
- MYH11 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55569420; called by muse, mutect2, varscan2
- N4BP3 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV99200708; called by mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, mutect2
- PCDH11X | c.2319T>A p.N773K | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100012348; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as rs752040289, COSV99240479; called by muse, mutect2, varscan2
- RASA3 | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV100480700; called by muse, mutect2
- RFX7 | c.374C>A p.A125D (on ENST00000559447 / NM_001368074.1; = p.A222D on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100428925; called by muse, mutect2, varscan2
- SMARCA1 | c.2251C>T p.R751* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV64412984; called by muse, mutect2, varscan2
- STPG2 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99759771; called by muse, mutect2
- TCF7L1 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs747610866, COSV56399352; called by muse, mutect2, varscan2
- USP34 | c.7195G>C p.D2399H | Missense Mutation (SNP) | VAF 25/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV101277069; called by muse, mutect2
- WFIKKN2 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as rs758406365, COSV60958676; called by muse, mutect2, varscan2
- ZNF41 | c.523dup p.I175Nfs*13 | Frame Shift Ins (INS) | VAF 13/127 reads (10%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.834C>T p.F278= (on ENST00000242786 / NM_078481.4; = p.F185= on NM_001784.5) | Silent (SNP) | VAF 6/104 reads (6%) | catalogued as COSV54409191, COSV54416782; called by muse, mutect2
- ARHGEF18 | c.2217C>T p.P739= (on ENST00000359920 / NM_001130955.2; = p.P635= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100149613; called by muse, mutect2, varscan2
- ATP8B4 | c.1671T>G p.L557= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV99466001; called by muse, mutect2
- FARP1 | c.942C>A p.A314= | Silent (SNP) | VAF 7/174 reads (4%) | catalogued as COSV100130945; called by muse, mutect2
- FAT4 | c.10185C>T p.V3395= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as COSV100628935; called by muse, mutect2, varscan2
- MAP3K9 | c.1722C>T p.G574= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as rs1433090669, COSV101173661; called by muse, mutect2, varscan2
- MAP9 | c.1146G>A p.K382= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100250925, COSV60904193; called by muse, mutect2
- PGAP1 | c.852C>T p.S284= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV100698236; called by muse, mutect2, varscan2
- PNMA3 | c.894A>G p.L298= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV100937613; called by muse, mutect2, varscan2
- SYNE3 | c.981C>G p.L327= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs748086812, COSV100516122; called by muse, mutect2
- USHBP1 | c.327G>A p.V109= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV99394309; called by muse, mutect2, varscan2
- ZNFX1 | c.5619G>A p.K1873= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as rs773169695, COSV100872418; called by muse, mutect2, varscan2
- FRMPD2B | n.746G>A | RNA (SNP) | VAF 26/384 reads (7%) | called by muse, mutect2
